Gene-level copy-number profile of tumor specimen TCGA-GD-A2C5-01A from TCGA case TCGA-GD-A2C5, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 53.4 years (19,498 days).
Specimen TCGA-GD-A2C5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.eb822df4-58af-442e-ad9b-d68618d6f4e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GD-A2C5-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebbf6a8f-d4eb-481c-948d-0a07104e28bd

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 5; copy number 1: 2,021; copy number 2: 10,129; copy number 3: 22,232; copy number 4: 16,754; copy number 5: 6,219; copy number 6: 807; copy number 7: 874; copy number 8: 53; copy number 9: 464; copy number 10: 27; copy number 11: 27; copy number 12: 76; copy number 15: 25; copy number 18: 27; copy number 21: 1; copy number 23: 26; copy number 24: 14; copy number 26: 8; copy number 27: 21.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GD-A2C5-01A-12D-A17S-01): tumor purity 1, ploidy 5.25, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): 5 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:91,642,643–92,660,863, 5 genes (within-gene range 0–2): AC093298.2, PCBP2P3, AC093298.1, AC114316.1, AC124854.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,643 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:39,026,318–40,072,649, 35 genes, copy number 21–26: NDUFS5, MACF1, RNU6-608P, RNA5SP44, AL442071.2, AL442071.1, HSPE1P8, BMP8A, OXCT2P1, PPIEL, PABPC4, PABPC4-AS1, SNORA55, HEYL, AL035404.2, NT5C1A, HPCAL4, PPIE, AL035404.1, RNU7-121P, BMP8B, OXCT2, BMP8B-AS1, AL033527.2, AL033527.1, AL033527.3, LINC02811, TRIT1, Y_RNA, MYCL, MYCL-AS1, Y_RNA, MFSD2A, AL663070.1, CAP1.
- chr1:103,415,980–104,226,678, 14 genes, copy number 15–24: AC095032.1, RN7SKP285, RNPC3, AMY2B, ACTG1P4, AMY2A, AMY1A, AC105272.1, AMY1B, AMYP1, AMY1C, AL136455.1, AC092506.1, FTLP17.
- chr1:109,466,546–109,930,992, 27 genes, copy number 18: SYPL2, ATXN7L2, CYB561D1, AMIGO1, GPR61, AL355310.3, GNAI3, RNU6V, AL355310.1, MIR197, GNAT2, AMPD2, AL355310.2, RPL7P8, GSTM4, GSTM2, GSTM1, AC000032.1, GSTM5, AL158847.1, GSTM3, EPS8L3, NDUFA5P10, LINC01768, AL450468.1, AL450468.2, CSF1.
- chr1:115,270,767–116,166,241, 21 genes, copy number 27: AL049825.1, NGF-AS1, NGF, AL512638.3, AL512638.1, AL512638.2, ELOCP20, CNOT7P2, AL592436.2, RN7SL420P, AL592436.1, VANGL1, CASQ2, NHLH2, HNRNPA1P43, LINC01649, AL357137.1, SLC22A15, AL365318.1, MAB21L3, LINC01779.
- chr4:71,741,696–74,007,682, 34 genes, copy number 9–15: GC, RNA5SP163, AC068721.1, NPFFR2, ADAMTS3, AC095056.1, HNRNPA1P67, RNU4ATAC9P, RNU6ATAC5P, COX18, ANKRD17, HMGA1P2, AC053527.2, AC053527.1, AC108157.1, ALB, AFP, AFM, LINC02499, AC074250.1, RASSF6, UMLILO, CXCL8, AC112518.1, CXCL6, PPBPP1, PF4V1, CXCL1, HNRNPA1P55, CXCL1P1, PF4, PPBP, CXCL5, AC097709.1.
- chr6:146,027,646–146,815,462, 10 genes, copy number 24: GRM1, FUNDC2P3, RNA5SP222, AL035698.1, RAB32, AL359547.1, ADGB, AL359547.2, RNU6-906P, KATNBL1P6.
- chr6:146,854,983–146,863,460, 1 gene, copy number 24: AL138916.1.
- chr8:36,378,069–38,382,272, 53 genes, copy number 8 (within-gene range 4–8): AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4, AC091182.1, AC091182.2, LINC01605, AC124067.1, AC124067.2, AC124067.3, AC124067.4, AC137579.2, AC137579.1, RNU6-607P, ZNF703, AC138356.3, AC138356.1, ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1.
- chr8:38,901,235–40,897,833, 30 genes, copy number 7 (within-gene range 3–7): PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D, ADAM32, RPL3P10, AC105185.1, ADAM5, ADAM3A, AC123767.1, ADAM18, ADAM2, AP005902.2, AP005902.1, IDO1, AC007991.3, AC007991.2, AC007991.4, IDO2, AC007991.1, AC087518.1, LINC02866, TCIM, AC022733.1, SIRLNT, AC105999.1, AC010857.1, ZMAT4.
- chr10:85,599,552–86,366,795, 1 gene, copy number 7 (within-gene range 3–7): GRID1.
- chr10:86,052,448–86,971,311, 18 genes, copy number 7: RNA5SP322, MIR346, AL844892.2, AL844892.1, WAPL, RNU6-780P, AL731569.1, RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1.
- chr10:86,970,237–86,970,826, 1 gene, copy number 7: AL136982.7.
- chr16:46,469,341–79,827,150, 840 genes, copy number 7–11 (broad region; genes not listed).
- chr17:26,981,694–30,959,322, 220 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).
- chr17:31,860,904–36,589,848, 195 genes, copy number 7–12 (within-gene range 3–12) (broad region; genes not listed).
- chr17:63,009,556–63,427,699, 1 gene, copy number 7 (within-gene range 4–7): TANC2.
- chr17:63,117,019–67,984,378, 142 genes, copy number 7 (within-gene range 6–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,579. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
